Gene-level copy-number profile of tumor specimen TCGA-50-5932-01A from TCGA case TCGA-50-5932, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.2 years (27,454 days).
Specimen TCGA-50-5932-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6e3bfcae-bea1-46b3-afee-df2e3a344cd1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5932-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/897c900e-6896-4c08-97ed-e3cbda1475d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 18,726; copy number 2: 35,936; copy number 3: 4,134; copy number 4: 613; copy number 5: 398.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5932-01A-11D-1752-01): tumor purity 0.84, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,850,283–196,918,713, 2 genes (within-gene range 0–2): BX248415.1, CFHR4.
- chr9:21,966,929–22,455,740, 10 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 398 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,796,030–207,917,088, 174 genes, copy number 5 (broad region; genes not listed).
- chr1:211,326,615–213,015,867, 59 genes, copy number 5: TRAF5, AL590101.1, LINC00467, SNX25P1, ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1, AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1, AC092803.3, NENF, LINC02771, AC092803.2, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A, AL590648.1, LINC02773, BATF3, NSL1, TATDN3, AC104333.3, SPATA45, FLVCR1-DT, AC104333.1, AC104333.2, FLVCR1, AC104333.4, VASH2, ANGEL2.
- chr1:235,975,830–240,475,187, 61 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr1:243,917,402–244,641,177, 14 genes, copy number 5 (within-gene range 4–5): LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5.
- chr1:247,297,412–248,919,946, 89 genes, copy number 5 (broad region; genes not listed).
- chr8:128,405,269–128,564,679, 1 gene, copy number 5 (within-gene range 3–5): LINC00824.

Autosomal genes at a single copy (total copy number 1): 16,340. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
